Surgical pathology report (de-identified scan), TCGA case TCGA-50-5044, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5044-01A (Primary Tumor).

FINAL DIAGNOSIS:

Summary Statement

The right lower lobe neoplasm is an invasive poorly differentiated adenocarcinoma, measuring 6.5 cm. Additional satellite nodules of adenocarcinoma are present. There is evidence of visceral pleural invasion and angiolymphatic invasion. All margins of resections are free of tumor. The interlobar (Part 4) and anterior hilar (Part 8) lymph nodes show evidence of metastatic carcinoma. The stage is T4 N1 Mx.

PART 1: LUNG, RIGHT LOWER LOBE, BIOPSY –
INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA.

PART 2: LUNG, RIGHT LOWER LOBE, LOBECTOMY –
A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA (6.5 CM) WITH EXTENSIVE NECROSIS, ABSCESS FORMATION, AND FOUR SATELLITE NODULES OF ADENOCARCINOMA (0.5 TO 2.0 CM). GRAM, GROCOTT, AND AFB STAINS ARE NEGATIVE FOR BACTERIAL, FUNGAL, AND MYCOBACTERIAL ORGANISMS IN THE INFLAMED NECROTIC AREA WITH ABSCESS FORMATION.
B. VISCERAL PLEURAL INVASION IS IDENTIFIED.
C. ALL MARGINS OF RESECTION FREE OF TUMOR.
D. ANGIOLYMPHATIC INVASION IDENTIFIED.
E. FOUR BENIGN REACTIVE PERIBRONCHIAL LYMPH NODES. NO CARCINOMA SEEN.
F. BACKGROUND LUNG SHOWING EMPHYSEMA.
G. STAGE T4 N1 MX.

PART 3: BONE, 6TH RIB, RESECTION –
SEGMENT OF BENIGN RIB WITH NO SIGNIFICANT ABNORMALITY. NO CARCINOMA SEEN.

PART 4: LYMPH NODE, INTERLOBAR, BIOPSY –
TWO OF FOUR (2/4) LYMPH NODES WITH METASTATIC CARCINOMA.

PART 5: LYMPH NODE, RIGHT LOWER LOBE, BIOPSY –
ONE BENIGN REACTIVE LYMPH NODE. NO CARCINOMA SEEN.

PART 6: LUNG, RIGHT MIDDLE LOBE, WEDGE RESECTION –
FOCUS OF ATYPICAL ADENOMATOUS HYPERPLASIA (0.8 CM). NO CARCINOMA SEEN.

PART 7: LUNG, RIGHT UPPER LOBE, WEDGE RESECTION –
PORTION OF BENIGN LUNG. NO CARCINOMA SEEN.

PART 8: LYMPH NODE, ANTERIOR HILAR, BIOPSY –
ONE LYMPH NODE WITH METASTATIC CARCINOMA.

PART 9: LYMPH NODE, SUBCARINAL, BIOPSY –
ONE BENIGN REACTIVE LYMPH NODE. NO CARCINOMA SEEN.

Source: NCI Genomic Data Commons file b17d3029-7400-4aea-a244-3fd405d68957 (TCGA-50-5044.40500921-FE3E-4FC0-A768-0062C488A832.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).